Somatic mutation profile of tumor specimen TCGA-CV-7101-01A (aliquot TCGA-CV-7101-01A-11D-2012-08) from TCGA case TCGA-CV-7101, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 80.9 years (29,550 days).
Specimen TCGA-CV-7101-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0310923d-a492-40e2-b7ff-ed7af7a344ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7101-10A (Blood Derived Normal), aliquot TCGA-CV-7101-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63dceffb-4e91-4873-8425-59c98c3dcdfe

The open-access MAF lists 182 somatic variants for this specimen: 129 protein-altering or splice-affecting, 47 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 47, Nonsense Mutation 12, Frame Shift Del 4, Intron 3, Frame Shift Ins 2, Splice Site 2, In Frame Del 1, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACHE | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV99574609; called by muse, mutect2, varscan2
- AMY2A | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV101340680; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2750C>G p.P917R | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99784583; called by muse, mutect2, varscan2
- APC | c.5095G>A p.E1699K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV57342499, COSV57381764; called by muse, mutect2, varscan2
- AREL1 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100707655; called by muse, varscan2
- ARSF | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs199811641, COSV100839500, COSV63839423; called by muse, mutect2, varscan2
- ASPG | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV101496454; called by muse, mutect2, varscan2
- ATR | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.084); catalogued as COSV100638624; called by muse, varscan2
- C11orf16 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs765220863, COSV100393898, COSV58167777, COSV58167853; called by muse, mutect2, varscan2
- C11orf16 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV100393901, COSV58167871; called by muse, mutect2, varscan2
- C6orf62 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100016142; called by muse, mutect2, varscan2
- CBX1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99848270; called by muse, varscan2
- CD163 | c.2891A>C p.Q964P | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100776158; called by muse, mutect2, varscan2
- CD200R1 | c.282G>C p.E94D (on ENST00000471858 / NM_170780.3; = p.E117D on NM_138806.4) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778113461, COSV55604755, COSV99867868; called by muse, mutect2
- CDH10 | c.189A>C p.L63F | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100050431, COSV100053248; called by muse, varscan2
- CDH11 | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99218232, COSV99219876; called by muse, mutect2, varscan2
- CDK12 | c.2938A>G p.R980G | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101420550; called by muse, mutect2, varscan2
- CDK15 | c.1087C>A p.L363M (on ENST00000652192 / NM_001366386.2; = p.L312M on NM_139158.2) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99643754; called by muse, mutect2, varscan2
- CENPT | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99535368; called by muse, mutect2
- CEP152 | c.2299C>G p.Q767E | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV100359205; called by muse, mutect2, varscan2
- CEP85L | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs768014159, COSV100821455; called by muse, mutect2, varscan2
- CEP97 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs753993583, COSV100512103; called by muse, mutect2, varscan2
- CES1 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100828821; called by muse, mutect2, varscan2
- CHRM3 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV55083588; called by muse, mutect2, varscan2
- CILP2 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176134907, COSV52281355; called by muse, mutect2, varscan2
- COL14A1 | c.3088A>G p.K1030E | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99920815; called by muse, mutect2
- CPNE1 | c.1480C>T p.R494W (on ENST00000352393; = p.R499W on NM_003915.5) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs757709412, COSV100467115, COSV100468169; called by muse, mutect2, varscan2
- CRB2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100749751; called by muse, mutect2, varscan2
- DENND5B | c.2963G>A p.G988E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170659; called by muse, mutect2, varscan2
- DIS3L2 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56056229, COSV99806684; called by muse, mutect2
- DMPK | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99353724; called by muse, mutect2, varscan2
- DOP1B | c.3245G>A p.G1082D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101215867; called by muse, mutect2, varscan2
- DPF2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.451); catalogued as rs1023937525, COSV99361991; called by muse, mutect2, varscan2
- DPYD | c.2134C>G p.P712A | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929493; called by muse, mutect2, varscan2
- EAF2 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV99877669; called by muse, mutect2, varscan2
- ENPP4 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100320473; called by muse, mutect2, varscan2
- EPB41L3 | c.3154-2A>T p.X1052_splice | Splice Site (SNP) | VAF 63/129 reads (49%) | catalogued as COSV100550415; called by muse, mutect2, varscan2
- FARP1 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100132231; called by muse, mutect2, varscan2
- FBN3 | c.7137C>A p.C2379* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV99561911; called by muse, mutect2, varscan2
- FCAR | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.053); catalogued as COSV100629214; called by muse, mutect2, varscan2
- GMDS | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as COSV101070643; called by muse, mutect2, varscan2
- GRID1 | c.2009A>C p.D670A | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100026764; called by muse, mutect2
- GRID2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99947303; called by muse, mutect2, varscan2
- GZMB | c.601G>C p.G201R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99362554; called by muse, mutect2
- HBA2 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99285444; called by muse, mutect2, varscan2
- HERC2 | c.12005C>A p.A4002D | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99876986; called by muse, mutect2, varscan2
- HTR1E | c.583T>A p.L195M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.34); catalogued as COSV100541338; called by muse, mutect2, varscan2
- IFIT5 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV65655934; called by mutect2, varscan2
- KDM1B | c.2269C>T p.R757W (on ENST00000449850; = p.R524W on NM_153042.4) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs756834832, COSV99924716; called by muse, mutect2, varscan2
- KHDRBS3 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs749093786, COSV100879057; called by muse, mutect2, varscan2
- KIF24 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100799377; called by muse, mutect2, varscan2
- KMT2A | c.11812G>A p.E3938K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100629988; called by muse, mutect2, varscan2
- KRT36 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs531137215, COSV100057758; called by muse, mutect2, varscan2
- KRTAP9-9 | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 82/261 reads (31%) | catalogued as COSV101223554; called by muse, mutect2, varscan2
- LAMA4 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100039552; called by muse, mutect2
- LILRA5 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as rs1161905623, COSV100007126; called by muse, mutect2, varscan2
- MAPK7 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55190145; called by muse, mutect2, varscan2
- MEI1 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs767158440, COSV100299601; called by muse, mutect2, varscan2
- MFN1 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54942213, COSV99764737; called by muse, mutect2
- MID1 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs755985917, COSV58196213; called by muse, mutect2, varscan2
- MYO3A | c.257T>A p.F86Y | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99781724; called by muse, mutect2
- MYO5B | c.3168G>A p.M1056I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1568623038; called by mutect2, varscan2
- NBEA | c.8072A>T p.Y2691F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV100084601; called by muse, mutect2, varscan2
- NLRP2 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV54753808, COSV99672694; called by muse, mutect2, varscan2
- NLRP6 | c.1601C>A p.A534D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV100381185, COSV56462287; called by muse, mutect2, varscan2
- NLRP9 | c.2941G>C p.D981H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV100243507; called by muse, mutect2, varscan2
- NOLC1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as rs1024297305; called by muse, mutect2
- NOTCH1 | c.5987C>T p.T1996M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773137647, COSV53079417; ClinVar: uncertain significance; called by mutect2, varscan2
- NYNRIN | c.4058C>T p.A1353V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101230711; called by muse, mutect2, varscan2
- OLIG3 | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as rs913822834, COSV100880346; called by muse, mutect2, varscan2
- OR2W3 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs781544814, COSV100831854; called by muse, mutect2
- PCDHB7 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.021); catalogued as rs782535815, COSV50762150, COSV50823479; called by muse, mutect2, varscan2
- PCDHGB5 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as rs1255452758; called by muse, mutect2, varscan2
- PCLO | c.1333G>T p.G445W | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV100438308; called by muse, mutect2, varscan2
- PEG3 | c.1985G>T p.C662F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV99690555; called by muse, mutect2, varscan2
- PKD1L2 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); catalogued as COSV61417844; called by muse, mutect2, varscan2
- PLD5 | c.485C>T p.S162L (on ENST00000442594; = p.S100L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100143088; called by muse, mutect2, varscan2
- PLEKHF1 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101460805; called by muse, mutect2, varscan2
- PLXNB2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100834334; called by muse, mutect2, varscan2
- PPFIA1 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs568113048, COSV99558060; called by muse, mutect2, varscan2
- QRFPR | c.1166A>C p.E389A | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV100543990; called by muse, mutect2
- RAB19 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99325250; called by muse, mutect2, varscan2
- RNF145 | c.1599C>A p.H533Q (on ENST00000424310 / NM_001199383.2; = p.H561Q on NM_144726.2) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99193889; called by muse, mutect2, varscan2
- RPH3AL | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs374739978; called by muse, mutect2, varscan2
- SEMA3C | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV99544007; called by muse, mutect2
- SEMA4A | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100740747; called by muse, mutect2, varscan2
- SH2B1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs144107554; called by muse, mutect2, varscan2
- SLC18A1 | c.1029G>T p.L343F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99368967; called by muse, mutect2, varscan2
- SLC25A22 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204316; called by muse, mutect2, varscan2
- SLITRK5 | c.2380C>A p.Q794K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV100281258; called by muse, mutect2, varscan2
- SNRNP200 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1050176644, COSV100108080; called by muse, mutect2, varscan2
- SRPRA | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV99703104; called by muse, mutect2, varscan2
- STK31 | c.1679C>A p.S560* | Nonsense Mutation (SNP) | VAF 39/140 reads (28%) | catalogued as COSV100669987; called by muse, mutect2, varscan2
- TMEM132D | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101243108; called by muse, mutect2, varscan2
- TMEM161A | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs761402280, COSV99365600; called by mutect2, varscan2
- TPO | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.624); catalogued as COSV100222251; called by muse, mutect2, varscan2
- TRGV3 | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs2392554; called by muse, mutect2, varscan2
- TRMT12 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100149185; called by muse, mutect2
- TROAP | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.242); catalogued as COSV99227043; called by muse, mutect2, varscan2
- TRRAP | c.7597C>T p.R2533C (on ENST00000359863 / NM_001244580.1; = p.R2515C on NM_003496.3) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs779095601, COSV62838331; called by muse, mutect2, varscan2
- TTN | c.28115C>A p.T9372N (on ENST00000591111; = p.T8445N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | PolyPhen benign (0); catalogued as COSV100631858; called by muse, mutect2, varscan2
- UBAP2 | c.2291C>T p.T764I | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100671989; called by muse, mutect2, varscan2
- UCK2 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV100903055, COSV63314899; called by muse, mutect2, varscan2
- UIMC1 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV101022225; called by muse, mutect2, varscan2
- USF3 | c.5041T>C p.S1681P | Missense Mutation (SNP) | VAF 102/140 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100325184, COSV100325842; called by muse, mutect2, varscan2
- USH2A | c.13282G>A p.G4428S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56340478; called by muse, mutect2
- VPS35L | c.409-1G>A p.X137_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99221793; called by muse, mutect2, varscan2
- XAB2 | c.2232G>T p.Q744H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99352077; called by muse, mutect2, varscan2
- YTHDF3 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV101572430; called by muse, mutect2, varscan2
- ZDHHC19 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99579850; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1430C>G p.S477* | Nonsense Mutation (SNP) | VAF 12/178 reads (7%) | catalogued as COSV100460400; called by muse, mutect2
- ZNF100 | c.1380C>A p.D460E | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533592689, COSV59747442; called by muse, mutect2, varscan2
- ZNF208 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs1419557057, COSV101237014; called by muse, mutect2, varscan2
- ZNF618 | c.1412A>G p.E471G (on ENST00000374126 / NM_001318042.2; = p.E378G on NM_133374.2) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99931105; called by muse, mutect2, varscan2
- ZNF654 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100525902; called by muse, mutect2, varscan2
- ZNF701 | c.1533G>T p.K511N (on ENST00000301093; = p.K445N on NM_018260.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV99991017; called by muse, mutect2, varscan2
- ZP4 | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100850784; called by muse, mutect2
- CUBN | c.1986del p.K663Sfs*38 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- DBR1 | c.404_412del p.G135_F137del | In Frame Del (DEL) | VAF 9/103 reads (9%) | called by mutect2, pindel
- HTR6 | c.769_781del p.T257Gfs*4 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- HYDIN | c.13916G>T p.C4639F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MYOCD | c.2525_2526insA p.F842Lfs*14 | Frame Shift Ins (INS) | VAF 4/53 reads (8%) | called by mutect2, pindel*
- NUMA1 | c.1243_1246del p.L415Kfs*3 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- SLC16A10 | c.613_632del p.I205Cfs*15 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel, varscan2
- SLC27A6 | c.1254dup p.G419Rfs*24 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- TRAV1-1 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ACTN2 | c.1458T>C p.I486= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100857062; called by muse, mutect2
- ASTN2 | c.2466G>A p.E822= (on ENST00000313400 / NM_001365069.1; = p.E771= on NM_014010.5) | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV100530563; called by muse, mutect2, varscan2
- BAG4 | c.696A>G p.S232= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99782068; called by muse, mutect2, varscan2
- BCAR1 | c.75C>A p.R25= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99367424; called by muse, mutect2, varscan2
- CARMIL2 | c.1848C>T p.I616= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100576335; called by muse, mutect2, varscan2
- CELF4 | c.546C>A p.T182= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100612061; called by muse, mutect2
- CLN8 | c.195C>T p.D65= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100486123; called by muse, mutect2, varscan2
- CNST | c.1107C>T p.A369= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as COSV100830123; called by muse, mutect2, varscan2
- CSMD3 | c.3916C>T p.L1306= (on ENST00000297405 / NM_001363185.1; = p.L1202= on NM_052900.3) | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs936727664, COSV99848959; called by muse, mutect2, varscan2
- CYFIP2 | c.2823C>A p.I941= (on ENST00000616178 / NM_001291722.2; = p.I916= on NM_014376.4) | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as COSV100557831; called by muse, mutect2, varscan2
- DEPDC5 | c.1044A>T p.L348= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV99836681; called by muse, mutect2, varscan2
- EDC4 | c.3936G>A p.P1312= | Silent (SNP) | VAF 35/236 reads (15%) | catalogued as rs1380408757, COSV59302279; called by muse, mutect2, varscan2
- FAM13A | c.786C>G p.P262= | Silent (SNP) | VAF 25/314 reads (8%) | catalogued as COSV99984744; called by muse, mutect2
- GNL3 | c.489G>A p.E163= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs1354654483, COSV101187286; called by muse, mutect2, varscan2
- HIRA | c.2283C>A p.S761= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as COSV99600938; called by muse, mutect2
- HMCN1 | c.16770G>A p.V5590= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs771454114, COSV99636371; called by muse, mutect2, varscan2
- KIAA1586 | c.282C>T p.S94= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100875398; called by muse, mutect2, varscan2
- KTI12 | c.885G>T p.G295= | Silent (SNP) | VAF 59/107 reads (55%) | catalogued as COSV100860274; called by muse, mutect2, varscan2
- LGSN | c.1278C>T p.A426= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs572903370, COSV65727079; called by muse, mutect2, varscan2
- MAGEA1 | c.9T>A p.L3= | Silent (SNP) | VAF 37/55 reads (67%) | catalogued as COSV100756686; called by muse, mutect2, varscan2
- MATN4 | c.975G>A p.E325= (on ENST00000372754; = p.E284= on NM_003833.4) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs750470331, COSV100637180; called by muse, mutect2
- MICAL3 | c.684C>T p.T228= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99263013; called by muse, mutect2, varscan2
- MTA1 | c.474G>A p.K158= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100495509; called by muse, mutect2, varscan2
- MYOD1 | c.57T>G p.S19= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100000438; called by muse, mutect2, varscan2
- OR2B11 | c.651C>T p.L217= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100276700; called by muse, mutect2, varscan2
- PARP15 | c.1401A>G p.A467= (on ENST00000464300 / NM_001113523.3; = p.A233= on NM_152615.2) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs772723454, COSV100117238; called by muse, mutect2, varscan2
- PCDHA5 | c.582T>G p.V194= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100972569; called by muse, mutect2, varscan2
- PLD1 | c.552A>G p.E184= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100578965; called by muse, mutect2
- PPFIA2 | c.3372A>G p.E1124= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100335407; called by muse, mutect2
- RYR2 | c.7569C>T p.A2523= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as rs748943528, COSV63715566; ClinVar: likely benign; called by muse, mutect2, varscan2
- SBF2 | c.198T>C p.F66= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99815875; called by muse, mutect2, varscan2
- SCGN | c.813G>T p.G271= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100618868; called by muse, mutect2, varscan2
- SLC28A1 | c.1773C>T p.Y591= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as COSV99723618; called by muse, mutect2, varscan2
- SLC47A2 | c.846C>T p.S282= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100328301; called by muse, mutect2, varscan2
- SLC7A7 | c.1317T>C p.D439= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs1323169057, COSV99591338; called by muse, mutect2, varscan2
- SLITRK5 | c.2379G>A p.Q793= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs781703614, COSV100281256; called by muse, mutect2, varscan2
- TBCD | c.1971G>A p.Q657= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100833803; called by muse, mutect2, varscan2
- TMEM150C | c.528C>T p.L176= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV101497325; called by muse, mutect2, varscan2
- TP53 | c.510G>T p.T170= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV52796495, COSV52850121, COSV53624945; called by muse, mutect2, varscan2
- TPPP2 | c.315C>A p.T105= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100409672; called by muse, mutect2, varscan2
- TTN | c.28116C>A p.T9372= (on ENST00000591111; = p.T8445= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100631854; called by muse, mutect2, varscan2
- WFS1 | c.1014C>T p.I338= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs748353498, COSV99901643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WHAMM | c.60C>T p.F20= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1385838150, COSV99725276; called by muse, mutect2, varscan2
- ZCCHC2 | c.3417C>T p.S1139= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs536205273, COSV54036934, COSV99502696; called by muse, mutect2, varscan2
- ZEB1 | c.2166A>G p.T722= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100315132; called by muse, mutect2, varscan2
- ZNF208 | c.1311C>T p.S437= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV101237142; called by muse, mutect2, varscan2
- ZNF536 | c.3117C>A p.V1039= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100836007; called by muse, mutect2, varscan2
- FGFR1 | c.937-1176C>T | Intron (SNP) | VAF 11/27 reads (41%) | catalogued as rs958859594, COSV100249351; called by muse, mutect2, varscan2
- KLHDC1 | c.-2G>C | 5'UTR (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99365003; called by muse, mutect2
- MIR517B | n.9C>G | RNA (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- PDE4B | c.635-41G>T | Intron (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100305225; called by muse, mutect2, varscan2
- PDE4B | c.635-40C>T | Intron (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100305226; called by muse, mutect2, varscan2
- STMP1 | chr7:135660556 G>A | 5'Flank (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
